Somatic mutation profile of tumor specimen C3L-07673-02 (aliquot CPT0453340006) from CPTAC case C3L-07673, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 70.1 years (25,609 days).
Specimen C3L-07673-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0dcd6cf-1f8c-4031-bda1-dedf1f34b519.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07673-31 (Blood Derived Normal), aliquot CPT0453480004; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/782bb27c-3045-44fe-affe-9327773583bd

The open-access MAF lists 35 somatic variants for this specimen: 27 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 4, Intron 3, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BMS1 | c.627A>C p.E209D | Missense Mutation (SNP) | VAF 9/212 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as COSV65734339; called by muse, mutect2
- CACNA1C | c.1327C>G p.Q443E | Missense Mutation (SNP) | VAF 18/474 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.759); catalogued as rs1458504552; called by muse, mutect2
- KANK2 | c.343G>C p.E115Q | Missense Mutation (SNP) | VAF 18/607 reads (3%) | SIFT tolerated (0.21); PolyPhen benign (0.078); catalogued as rs1349314165; called by muse, mutect2
- KLRB1 | c.128T>G p.L43R | Missense Mutation (SNP) | VAF 13/278 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs935506623, COSV57589352, COSV57589826; called by muse, mutect2
- PLD5 | c.1359T>G p.N453K (on ENST00000442594; = p.N391K on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/233 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV100139960, COSV59171604; called by muse, mutect2
- AKAP13 | c.2779G>C p.D927H | Missense Mutation (SNP) | VAF 16/338 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); called by muse, mutect2
- CFAP54 | c.5702T>C p.L1901P | Missense Mutation (SNP) | VAF 12/282 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- CYRIA | c.836A>C p.D279A | Missense Mutation (SNP) | VAF 9/231 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.174); called by muse, mutect2
- DAG1 | c.1110C>G p.I370M | Missense Mutation (SNP) | VAF 19/498 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.009); called by muse, mutect2
- ECM2 | c.1828C>G p.L610V | Missense Mutation (SNP) | VAF 12/331 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- EDC4 | c.2117C>T p.A706V | Missense Mutation (SNP) | VAF 28/401 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.037); called by muse, mutect2
- EFCAB5 | c.954A>C p.Q318H | Missense Mutation (SNP) | VAF 16/275 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); called by muse, mutect2
- FER1L5 | c.5178C>G p.I1726M (on ENST00000623019; = p.I1699M on NM_001293083.2) | Missense Mutation (SNP) | VAF 16/331 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- GKN3P | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 18/384 reads (5%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.928); called by muse, mutect2
- KRTAP13-2 | c.212T>C p.V71A | Missense Mutation (SNP) | VAF 17/496 reads (3%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); called by muse, mutect2
- LCE1D | c.115T>C p.C39R | Missense Mutation (SNP) | VAF 13/356 reads (4%) | PolyPhen possibly damaging (0.571); called by muse, mutect2
- LRRC30 | c.77A>C p.K26T | Missense Mutation (SNP) | VAF 14/413 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.136); called by muse, mutect2
- LRRC31 | c.1414A>G p.M472V | Missense Mutation (SNP) | VAF 20/424 reads (5%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2
- MARS1 | c.157C>G p.L53V | Missense Mutation (SNP) | VAF 16/342 reads (5%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.46); called by muse, mutect2
- NEIL3 | c.947A>C p.K316T | Missense Mutation (SNP) | VAF 12/340 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.543); called by muse, mutect2
- OR10G6 | c.544A>G p.S182G | Missense Mutation (SNP) | VAF 12/450 reads (3%) | SIFT tolerated (0.34); PolyPhen benign (0.421); called by muse, mutect2
- OR56B1 | c.661A>C p.S221R | Missense Mutation (SNP) | VAF 14/384 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.356); called by muse, mutect2
- PLXDC2 | c.1055T>G p.L352R | Missense Mutation (SNP) | VAF 9/245 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- POM121L12 | c.665A>C p.K222T | Missense Mutation (SNP) | VAF 22/574 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- TSHZ2 | c.2164A>C p.S722R | Missense Mutation (SNP) | VAF 16/524 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.186); called by muse, mutect2
- UBE2Q2 | c.862G>T p.V288L | Missense Mutation (SNP) | VAF 16/264 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.188); called by muse, mutect2
- ZDBF2 | c.2949A>C p.E983D | Missense Mutation (SNP) | VAF 13/368 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); called by muse, mutect2
- FER1L5 | c.5493C>G p.V1831= (on ENST00000623019; = p.V1795= on NM_001293083.2) | Silent (SNP) | VAF 18/288 reads (6%) | called by muse, mutect2
- GAS6 | c.1575C>G p.L525= | Silent (SNP) | VAF 19/491 reads (4%) | called by muse, mutect2
- UNC5C | c.1791A>G p.P597= | Silent (SNP) | VAF 17/420 reads (4%) | called by muse, mutect2
- ZNF316 | c.2352C>T p.F784= | Silent (SNP) | VAF 29/583 reads (5%) | called by muse, mutect2
- FBRS | chr16:30659674 C>G | 5'Flank (SNP) | VAF 26/546 reads (5%) | called by muse, mutect2
- KCNT2 | c.2910+7380A>C | Intron (SNP) | VAF 13/285 reads (5%) | catalogued as COSV54084471; called by muse, mutect2
- NAV3 | c.2024-12918T>G | Intron (SNP) | VAF 9/301 reads (3%) | called by muse, mutect2
- NEB | c.8890-3117A>C | Intron (SNP) | VAF 11/285 reads (4%) | called by muse, mutect2
